Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PR, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PR-01A (Primary Tumor).

[page 1 of 3]
NIHAA Discrepancy		✓

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

ear old with papillary carcinoma left thyroid. Papillary thyroid carcinoma.

Specimens Submitted:

- 1: Thyroid gland, right lobe; hemithyroidectomy
- 2: Thyroid gland, left lobe; hemithyroidectomy
- 3: Lymph nodes, left paratracheal; dissection

DIAGNOSIS:

1. Thyroid gland, right lobe; hemithyroidectomy:

- Papillary thyroid microcarcinoma, 0.15 cm in greatest dimension, located in the right lobe
- No extrathyroidal extension or vascular invasion is noted
- Margins are free of tumor
- Psammoma bodies are noted in the surrounding thyroid tissue
- Chronic lymphocytic thyroiditis and nodular hyperplasia
- Two psammoma bodies are noted involving one of two lymph nodes consistent with metastatic papillary thyroid carcinoma (1/2)

2. Thyroid gland, left lobe; hemithyroidectomy:

Tumor Type: Papillary carcinoma, classical type

Histologic Grade: Well differentiated

Mitotic Activity: Not identified

Tumor Necrosis: Not identified

Tumor Location: Left lobe

Tumor Size: Greatest diameter is 2 cm.

Tumor Encapsulation: Completely surrounded

Capsular Invasion: Focal invasion

Blood Vessel Invasion: Not identified

Extrathyroid Extension:

1CD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NIS C73.9

lw
8/31/11

[page 2 of 3]
Invades:extrathyroidal adipose tissue
focal

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic foci present

One focus of papillary microcarcinoma is noted in the left lobe measuring 0.2 cm

Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

Comment: Psammoma bodies are noted in the non-neoplastic thyroid tissue.

3. Lymph nodes, left paratracheal; dissection:

Lymph Node Dissection:

Metastatic papillary thyroid carcinoma

Number of lymph nodes examined: 12

Number of lymph nodes with metastatic disease: 6

Size of the largest lymph node involved by tumor: 0.6cm.

Size of the largest metastatic focus : 0.4 cm.

Extranodal extension is not identified

Comment: Some of the positive lymph nodes show only psammoma bodies.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

M.D.

1. The specimen is received fresh, labeled "right thyroid" and consists of a 6.5g, 4.3 x 2.2 x 1.2 cm right thyroid lobe oriented by a long and a short stitch as per requisition. The external surface is free of abnormalities; the posterior is inked black, the anterior is inked blue and the isthmus green. The cut surface reveals a slightly pale, firm cut surface, free of focal lesions. The entire lobe is submitted.

Summary of sections:

RL - right lobe of thyroid, serially sectioned, submitted from superior to inferior.

J, M.D.

2. The specimen is received fresh, labeled "left thyroid lobe" and consists of a 25g left lobe of thyroid and isthmus, 5.0 x 2.0 x 2.5 cm, oriented by a long and a short stitch as per requisition. The external surface is free of abnormalities. The posterior is inked black, the anterior is inked blue and the isthmus green. The cut surface reveals a bright yellow papillary soft lesion in the lower pole, 2.0 x 1.8 x 1.6 cm, surrounding by some fibrosis. It is 0.2 cm from the anterior and posterior surfaces and 0.6 cm from the isthmus margin. The tumor is entirely submitted for TPS and permanent sections. The remaining thyroid lobe is entirely submitted.

Summary of sections:

[page 3 of 3]
T - lesion, serially sectioned.
LL - remaining

3) The specimen is received fresh, labeled "left para-tracheal lymph node" and consists of multiple pink tan firm lymph nodes ranging from 0.2 x 0.2 x 0.2 cm to 0.5 x 0.3 x 0.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
LN - lymph nodes

Summary of Sections:

Part 1: Thyroid gland, right lobe; hemithyroidectomy

Block	Sect. Site	PCs
6	RL	6

Part 2: Thyroid gland, left lobe; hemithyroidectomy

Block	Sect. Site	PCs
6	LL	6
3	T	3

Part 3: Lymph nodes, left paratracheal; dissection

Block	Sect. Site	PCs
2	ln	2

Source: NCI Genomic Data Commons file 0a0d9f63-7f32-49b0-a246-b2572e8e99f4 (TCGA-DJ-A2PR.B78B9C06-DE73-47A9-A32A-73F60351433A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).